Surgical pathology report (de-identified scan), TCGA case TCGA-EP-A3RK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-EP-A3RK-01A (Primary Tumor).

Final Surgical Pathology Report

Procedure:

Diagnosis

Liver, left lobe, partial hepatectomy:
Moderately differentiated hepatocellular carcinoma.
The margins of resection are free of carcinoma.

Microscopic Description:

Histologic type: Hepatocellular carcinoma
Histologic grade: Moderately differentiated
Tumor size: Tumor measures maximally 8.7 x 7.4 x 6.0 cm
Primary tumor (pT): pT3a
Margins of resection: Negative
Vascular invasion: Positive
Regional lymph nodes (pN): pNx
Distant metastasis (pM): pMx

Specimen

A. Left liver

Clinical Information

Liver carcinoma

Gross Description

A. Received fresh for tissue procurement labeled "left liver" is a 425 g, wedge-shaped, 21.0 x 11.5 x 6.5 cm portion of red-brown liver parenchyma with a 16.5 x 2.4 x 1.2 cm fatty pedicle along one aspect (in keeping with ligament of . The capsular surface is deformed by a bosselated firm subcapsular mass. On sectioning, the mass is lobulated pale tan-yellow to tan-pink, measuring 8.7 x 7.4 x 6.0 cm. A portion of the tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The tumor extends to within less than 0.1 cm of the inked capsular surface and is 3.2 cm from the cauterized margin of resection. A pale firm focus measuring 3 cm in greatest dimension is noted at the margin (in keeping with cautery artifact see block 5). The remaining liver parenchyma is uniform red-brown without additional mass lesion or abnormality.
Summary: 1 through 4 - tumor to inked capsular surface, 5 - closest margin of resection including additional pale focus, 6 through 8 - tumor to normal parenchyma, 9 - random parenchyma, 10 - parenchyma to attached ligament

ICD-O-3

carcinoma, hepatocellular, NOS

8170/3

Site: liver C22.0

3/9/12 RD

I-PAA Discrepancy		☒
Reviewer Initials	W3/7/12	

Source: NCI Genomic Data Commons file 3efe5aed-4f2f-4d05-b63e-7f1e4cbd8550 (TCGA-EP-A3RK.49F4E752-EFBE-458F-85C0-1B81B9506D91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).